Gene-level copy-number profile of tumor specimen TCGA-N8-A56S-01A from TCGA case TCGA-N8-A56S, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Age at diagnosis: 75.3 years (27,519 days).
Specimen TCGA-N8-A56S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.6f8e45b3-6ed7-4f94-b5b5-dffeeeef1f59.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N8-A56S-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ffe988fc-270c-4f97-9ba0-fc47e1a4cc06

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 259; copy number 2: 8,683; copy number 3: 12,412; copy number 4: 34,063; copy number 5: 1,751; copy number 6: 1,121; copy number 7: 1,272; copy number 8: 21; copy number 9: 8; copy number 11: 10; copy number 12: 28; copy number 16: 107; copy number 25: 53; copy number 59: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N8-A56S-01A-11D-A28Q-01): tumor purity 0.75, ploidy 3.48, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 229 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:126,556,323–127,419,050, 1 gene, copy number 59 (within-gene range 3–59): PCAT1.
- chr8:127,072,694–128,187,101, 22 genes, copy number 59 (within-gene range 3–59): CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207.
- chr13:72,453,902–73,016,461, 12 genes, copy number 12 (within-gene range 6–12): AL139003.1, RPL18AP17, AL139003.2, AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P.
- chr16:10,944,564–11,182,186, 1 gene, copy number 12 (within-gene range 6–12): CLEC16A.
- chr16:11,066,496–11,381,662, 15 genes, copy number 12 (within-gene range 6–12): AC007014.1, AC007220.2, AC007220.1, HNRNPCP4, RMI2, SOCS1, TNP2, PRM3, AC009121.1, PRM2, PRM1, AC009121.4, MIR548H2, Y_RNA, AC009121.3.
- chr17:47,323,290–49,583,827, 117 genes, copy number 11–16 (within-gene range 7–16) (broad region; genes not listed).
- chr17:60,677,453–61,392,838, 1 gene, copy number 9 (within-gene range 4–9): BCAS3.
- chr17:61,034,636–61,400,243, 7 genes, copy number 9 (within-gene range 4–9): AC005884.1, AC005884.2, RPL23AP74, AC005856.1, AC005746.3, AC005746.2, AC005746.1.
- chr20:31,257,664–32,277,510, 53 genes, copy number 25: DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, AL121897.1.

Autosomal genes at a single copy (total copy number 1): 259. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
